Somatic mutation profile of tumor specimen ASCProject_0194_T2_WES (aliquot ASCProject_0194_T2_WES_1) from CMI case ASCProject_0194, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Heart; Age at diagnosis: 32.3 years (11,785 days).
Specimen ASCProject_0194_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Heart; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8fe975f-2a96-4e84-bf2c-525674a46b13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0194_SALIVA (Saliva), aliquot ASCProject_0194_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/481a6e71-c02c-437a-b77a-b1fc4ae2eb24

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Splice Site 2, Nonsense Mutation 2, Intron 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2
- MKRN2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/302 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as rs1470328530; called by muse, mutect2
- REPIN1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 14/373 reads (4%) | catalogued as rs1290717908; called by muse, mutect2
- RNF213 | c.12022G>A p.V4008I | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs762259446; called by muse, mutect2, varscan2
- MYH1 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PCCB | c.966+2T>C p.X322_splice | Splice Site (SNP) | VAF 27/636 reads (4%) | called by muse, mutect2
- PLCG1 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNLIP | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- R3HCC1 | c.1313-1G>A p.X438_splice (on ENST00000411463; = p.X398_splice on NM_001136108.3) | Splice Site (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- RET | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- SCN2A | c.4206A>T p.K1402N | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAG1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD163 | c.3315A>T p.A1105= | Silent (SNP) | VAF 15/199 reads (8%) | called by muse, mutect2
- GAN | c.1128G>A p.L376= | Silent (SNP) | VAF 40/436 reads (9%) | called by muse, mutect2
- RAD51AP2 | c.666A>G p.K222= | Silent (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- TTLL6 | c.2535G>A p.L845= (on ENST00000393382 / NM_001130918.3; = p.L538= on NM_173623.3) | Silent (SNP) | VAF 17/193 reads (9%) | catalogued as rs1238057925; called by muse, mutect2
- DPH6 | c.312+16000T>A | Intron (SNP) | VAF 11/102 reads (11%) | catalogued as rs1268694895; called by muse, mutect2
- PDE2A | c.1538-14T>C | Intron (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
